Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A718, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A718-01A (Primary Tumor).

ICD-O-3 NOS
Carcinoma, squamous cell
867013
Site Larynx NOS
C32.9
7/28/13

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

- 1 - "Lymph Nodes - Level 6 - Left":
- Three lymph nodes with no evidence of metastatic carcinoma (0/3).
- 2 - "Total laryngectomy specimen and bilateral jugular-carotid lymph nodes":
- Moderately differentiated squamous cell carcinoma involving bilaterally infraglottic, glottic and supraglottic regions and extends to right hypopharynx.
- Tumor size: 4.5 x 4.0 x 3.5 cm.
- Tumor involves thyroid cartilage and right paralaryngeal skeletal muscle.
- "In situ" squamous cell carcinoma associated.
- Moderate stromal dysplasia
- Perineural invasion: absent
- Lymphovascular invasion: absent
- Margins uninvolved by carcinoma.
- Twelve lymph nodes at right with no evidence of metastatic carcinoma (0/12) and ten lymph nodes at left with no evidence of metastatic carcinoma (0/10).
- Pre-epiglottic fat tissue no evidence of neoplasia.

Source: NCI Genomic Data Commons file 46cfa41c-fb6e-4c19-b886-8c4ebc69f4d7 (TCGA-UF-A718.5EDE84B0-C93C-426A-983D-A0CE61092BFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).